MP2PRT case MP2PRT-PAPKRX — Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia (MP2PRT-ALL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/e068d7b6-eea4-4606-8f8a-532e9f29c1d9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 3 years; Year of birth: 2003; Vital status: Alive.

Diagnoses (1)
1. Acute lymphoblastic leukemia, NOS: Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 3.0 years (1,109 days); Year of diagnosis: 2006; Days to last follow up: 4,260 days (11.7 years).
   Treatment given: Initial disease status: Initial Diagnosis; Regimen or line of therapy: SR-Low Group - LRS arm:  Standard Consolidation, Standard Interim Maintenance, Standard Delayed Inte; Days to treatment start: 0 days; Days to treatment end: 795 days (2.2 years); Number of cycles: 5; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Treatment anatomic sites: Body, total.

Follow-up (1 entry)
- Days to follow up: 4,260 days (11.7 years); Disease response: Complete Response; Progression or recurrence: No; Days progression-free: 4,260 days (11.7 years).

Molecular and laboratory tests
- ABL1 (FISH): Negative.
- BCR (FISH): Negative.
- ETV6 (FISH): Negative.
- RUNX1 (FISH): Negative.

Biospecimens (2 samples)
- Sample MP2PRT-PAPKRX-NB1-A: Sample type: Blood Derived Cancer - Peripheral Blood, Post-treatment; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
- Sample MP2PRT-PAPKRX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
